Somatic mutation profile of tumor specimen MP2PRT-PASSIK-TMP1-A (aliquot MP2PRT-PASSIK-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASSIK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,648 days).
Specimen MP2PRT-PASSIK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76531934-2af4-4ce2-87e5-08bb73a4896c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASSIK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASSIK-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a65a8382-63b1-4829-b721-2c168648b7bb

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 72/266 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 19/287 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AL645922.1 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 150/639 reads (23%) | catalogued as rs1380436901; called by muse, mutect2, varscan2
- CUL7 | c.2323A>T p.M775L | Missense Mutation (SNP) | VAF 40/604 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1432659911; called by muse, mutect2
- ESAM | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 179/412 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as rs200474387; called by muse, mutect2, varscan2
- IHH | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 152/395 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as rs145192358, COSV99838784; called by muse, mutect2, varscan2
- LIPG | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 82/433 reads (19%) | catalogued as rs777046276, COSV99724839; called by muse, mutect2, varscan2
- SCN1A | c.2686G>A p.V896I (on ENST00000303395 / NM_001202435.3; = p.V885I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.572); catalogued as rs745378416, CM096133, CM1211401, CM127610, COSV57687946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM3 | c.6887C>T p.S2296L | Missense Mutation (SNP) | VAF 71/383 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs754948569, COSV69312053; called by muse, mutect2, varscan2
- TPBG | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 87/394 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); catalogued as rs138578663; called by muse, mutect2, varscan2
- UGT8 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 77/400 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.18); catalogued as rs1413852774; called by muse, mutect2, varscan2
- DRG1 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHROOM4 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 127/412 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHA11 | c.1968G>A p.P656= | Silent (SNP) | VAF 112/422 reads (27%) | called by muse, mutect2, varscan2
- TEAD3 | c.111G>A p.P37= | Silent (SNP) | VAF 24/820 reads (3%) | catalogued as rs958937249, COSV100132555; called by muse, mutect2
- UNC79 | c.6129G>A p.P2043= (on ENST00000393151 / NM_001346218.2; = p.P1866= on NM_020818.5) | Silent (SNP) | VAF 45/865 reads (5%) | catalogued as rs188210962, COSV56389512; called by muse, mutect2
